Somatic mutation profile of tumor specimen TCGA-2G-AAGI-01A (aliquot TCGA-2G-AAGI-01A-11D-A42Y-10) from TCGA case TCGA-2G-AAGI, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed germ cell tumor; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 33.9 years (12,366 days).
Specimen TCGA-2G-AAGI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6c2e9f04-e1e1-415b-b3c1-e80aef8ef2ba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAGI-10A (Blood Derived Normal), aliquot TCGA-2G-AAGI-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d78e1110-1332-4cff-a1ba-fd638b9ff5af

The open-access MAF lists 16 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Intron 2, Silent 2, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL1 | c.578G>A p.C193Y | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1237338977; called by muse, mutect2
- HECTD4 | c.8326G>A p.A2776T | Missense Mutation (SNP) | VAF 60/187 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1183118449; called by muse, mutect2, varscan2
- ITPR1 | c.4725G>T p.M1575I (on ENST00000354582; = p.M1560I on NM_002222.7) | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.017); catalogued as COSV56977420; called by muse, mutect2, varscan2
- UMODL1 | c.1677G>A p.M559I | Missense Mutation (SNP) | VAF 63/275 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs200274014, COSV100210669; called by muse, mutect2, varscan2
- KLHDC2 | c.962G>C p.W321S | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MSH6 | c.1727A>C p.D576A | Missense Mutation (SNP) | VAF 73/209 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PLIN2 | c.-22A>G | Splice Region (SNP) | VAF 41/89 reads (46%) | called by muse, mutect2, varscan2
- PSME4 | c.1483A>G p.N495D | Missense Mutation (SNP) | VAF 41/158 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- PTPN20 | c.590C>T p.S197L | Missense Mutation (SNP) | VAF 65/301 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- STON1 | c.1352A>G p.N451S | Missense Mutation (SNP) | VAF 42/177 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- WNT5B | c.979A>G p.K327E | Missense Mutation (SNP) | VAF 51/126 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- DSG2 | c.2262C>T p.S754= | Silent (SNP) | VAF 31/82 reads (38%) | called by muse, mutect2, varscan2
- TET1 | c.288C>G p.S96= | Silent (SNP) | VAF 37/99 reads (37%) | called by muse, mutect2, varscan2
- LRP5L | n.322C>T | RNA (SNP) | VAF 66/116 reads (57%) | called by muse, mutect2, varscan2
- PTCH1 | c.202-20C>T | Intron (SNP) | VAF 56/64 reads (88%) | called by muse, mutect2, varscan2
- TAF1 | c.5002-334G>T | Intron (SNP) | VAF 4/64 reads (6%) | catalogued as rs1463333690; called by muse, mutect2
